Gene-level copy-number profile of tumor specimen TCGA-CS-5395-01A from TCGA case TCGA-CS-5395, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 43.4 years (15,848 days).
Specimen TCGA-CS-5395-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.68059f9b-85af-45c2-a5ad-d7456f57eb20.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CS-5395-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/35854733-8d3d-4cfa-86c7-66750e303bb7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 5,821; copy number 2: 45,377; copy number 3: 8,508; copy number 6: 8; copy number 18: 4; copy number 19: 5; copy number 20: 44; copy number 24: 7; copy number 26: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CS-5395-01A-01D-1466-01): tumor purity 0.81, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,128,103, 10 genes (within-gene range 0–1): AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 100 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:202,724,495–202,812,156, 5 genes, copy number 19 (within-gene range 1–19): KDM5B, AC098934.1, SLC25A39P1, AC098934.2, PCAT6.
- chr1:203,729,581–204,685,738, 36 genes, copy number 18–26 (within-gene range 1–26): SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2.
- chr1:209,744,373–210,171,389, 7 genes, copy number 24 (within-gene range 1–24): ADORA2BP1, TRAF3IP3, C1orf74, IRF6, UTP25, SYT14, AL022397.1.
- chr1:226,318,015–227,846,470, 44 genes, copy number 20 (within-gene range 1–20): YBX1P9, AL359742.1, PARP1, AL359704.1, RPS3AP7, RN7SKP165, CDKN2AIPNLP1, AL359704.2, STUM, ITPKB, ITPKB-IT1, ITPKB-AS1, RPS27P5, AL359732.1, PSEN2, AL391628.1, COQ8A, AL353689.1, CDC42BPA, AL353689.2, AL353689.3, AL451047.1, AL627308.1, AL627308.2, AL627308.3, LINC01641, NUCKS1P1, AL606462.1, BTF3P9, AL451054.2, AL451054.3, TUBB8P10, TUBB8P9, AL451054.1, AL451054.4, RNA5SP77, ZNF678, FAM133FP, ZNF847P, SNAP47, JMJD4, SNAP47-AS1, AL731702.1, PRSS38.
- chr7:38,257,879–38,311,808, 8 genes, copy number 6: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.

Autosomal genes at a single copy (total copy number 1): 3,440. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
